CCDI case PBBXXP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/ba72631a-5d2e-4df0-b1f8-22f96c557b61

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 16.5 years (6,026 days).

Biospecimens (3 samples)
- Sample 0DKIHS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKII4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKII9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
